Somatic mutation profile of tumor specimen TCGA-AX-A3G4-01A (aliquot TCGA-AX-A3G4-01A-11D-A20S-09) from TCGA case TCGA-AX-A3G4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.5 years (22,099 days).
Specimen TCGA-AX-A3G4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b22f341-445c-402b-bb9c-05195bc4e4ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A3G4-10A (Blood Derived Normal), aliquot TCGA-AX-A3G4-10A-01D-A20S-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72a9f18d-1c17-4370-b11a-7d8c51c9983d

The open-access MAF lists 42 somatic variants for this specimen: 34 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 23, Silent 8, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 2, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 42/85 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as rs121913275, COSV55874040, COSV55875881, COSV55956933; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 32/38 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMER1 | c.3089T>A p.M1030K | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100366949; called by muse, mutect2, varscan2
- CDX4 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100999151; called by muse, mutect2, varscan2
- DMXL1 | c.5300A>T p.H1767L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV100224824; called by muse, mutect2, varscan2
- DMXL1 | c.7621C>T p.L2541F | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100224828; called by muse, mutect2, varscan2
- EIF4A1 | c.719A>G p.E240G | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV99549217; called by muse, mutect2, varscan2
- JRK | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV101401150; called by muse, mutect2, varscan2
- KIR3DL3 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1380734461, COSV52545531; called by muse, mutect2, varscan2
- LAMA2 | c.2826C>G p.N942K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV101370780; called by muse, mutect2, varscan2
- MPP5 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV99907366; called by muse, mutect2, varscan2
- NAA11 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs748343608, COSV54514751; called by mutect2, varscan2
- NBEA | c.6238C>T p.R2080* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV59773827; called by muse, mutect2, varscan2
- OR2M7 | c.756T>G p.Y252* | Nonsense Mutation (SNP) | VAF 70/219 reads (32%) | catalogued as COSV100522664; called by muse, mutect2, varscan2
- PCDHGA2 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs749260209, COSV53932016; called by muse, mutect2, varscan2
- RHPN2 | c.760+1G>T p.X254_splice | Splice Site (SNP) | VAF 26/80 reads (33%) | catalogued as rs772781302, COSV99578203; called by muse, mutect2, varscan2
- RUNX1T1 | c.991+1G>A p.X331_splice (on ENST00000265814 / NM_001198628.1; = p.X304_splice on NM_004349.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 93/242 reads (38%) | catalogued as COSV56157330; called by muse, mutect2, varscan2
- SLC22A15 | c.453A>C p.L151F | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV101047379; called by muse, mutect2, varscan2
- SLC25A31 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1490930808, COSV99829613; called by muse, mutect2, varscan2
- SPHK1 | c.68C>G p.P23R (on ENST00000392496 / NM_001355139.2; = p.P37R on NM_021972.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100039521; called by muse, mutect2
- TCF4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/21 reads (52%) | SIFT deleterious, low confidence (0); catalogued as COSV101261049; called by muse, mutect2, varscan2
- TNXB | c.7655G>A p.R2552H (on ENST00000647633; = p.R2305H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.09); catalogued as rs763647914, COSV100926587; called by muse, mutect2
- TOR3A | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV100751404; called by muse, mutect2, varscan2
- TRPV5 | c.331A>G p.T111A | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs757103149, COSV99520954; called by muse, mutect2, varscan2
- TTN | c.23090T>C p.I7697T (on ENST00000591111; = p.I6770T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | PolyPhen possibly damaging (0.544); catalogued as rs1415104830, COSV100626986, COSV59952950; called by muse, mutect2
- UGT1A3 | c.286C>A p.H96N | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100530905; called by muse, mutect2
- USP15 | c.454T>C p.F152L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs1323367828; called by muse, mutect2
- VCP | c.2034G>A p.M678I | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100734340; called by muse, mutect2, varscan2
- DNAH8 | c.12865_12866del p.M4289Efs*2 | Frame Shift Del (DEL) | VAF 59/170 reads (35%) | called by mutect2, pindel, varscan2
- ERRFI1 | c.954dup p.V319Sfs*11 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- PTEN | c.648_650del p.V217del | In Frame Del (DEL) | VAF 37/57 reads (65%) | called by mutect2, pindel, varscan2
- TLR4 | c.1102dup p.S368Ffs*4 (on ENST00000355622 / NM_138554.5; = p.S328Ffs*4 on NM_003266.4) | Frame Shift Ins (INS) | VAF 12/20 reads (60%) | called by mutect2, pindel, varscan2
- TRAV8-3 | c.278T>C p.F93S | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- WWC2 | c.3473_3491del p.E1158Vfs*19 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- ADAM2 | c.2028T>C p.I676= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs778859383, COSV99697797; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.1935A>G p.G645= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV99784277; called by muse, mutect2, varscan2
- ANKLE1 | c.963G>A p.T321= (on ENST00000394458; = p.T267= on NM_152363.6) | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs572737095, COSV63921201; called by muse, mutect2, varscan2
- CCDC141 | c.3516A>C p.T1172= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV99837365; called by muse, mutect2, varscan2
- NUP37 | c.60T>C p.H20= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV99195864; called by muse, mutect2, varscan2
- P4HA3 | c.429G>C p.L143= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100525883; called by muse, mutect2, varscan2
- PHGDH | c.51T>C p.P17= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV101026382; called by muse, mutect2
- TPX2 | c.723T>C p.A241= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100302024; called by muse, mutect2, varscan2
